Somatic mutation profile of tumor specimen 0DOBTF from CCDI case PBCCKU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,689 days).
Specimen 0DOBTF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3eb7c83-2082-4791-81c3-e470656d1800.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOBSU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28603e92-0843-48d4-9d72-97ae1cfb864d

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LLGL1 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 33/790 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.25); catalogued as rs1212774836; called by muse, mutect2
- PTPRK | c.4178T>C p.V1393A (on ENST00000368215 / NM_001291984.2; = p.V1394A on NM_002844.4) | Missense Mutation (SNP) | VAF 26/776 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- MBP | c.396T>C p.D132= | Silent (SNP) | VAF 102/559 reads (18%) | called by muse, mutect2, varscan2
